Somatic mutation profile of cancer-model specimen HCM-BROD-0413-C25-85O (3D Organoid, passage 6; aliquot HCM-BROD-0413-C25-85O-01D-A85E-36), derived from the metastatic tumor of HCMI case HCM-BROD-0413-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 53.1 years (19,390 days).
Specimen HCM-BROD-0413-C25-85O: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe50a9aa-8686-45ac-bdd1-a8f5b32a24b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0413-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0413-C25-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29b545a4-de2b-4b4b-acb4-221545d6b3c7

The open-access MAF lists 45 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Frame Shift Del 2, Nonsense Mutation 2, Intron 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238del p.R80Dfs*66 | Frame Shift Del (DEL) | VAF 225/582 reads (39%) | catalogued as rs1563889584, CM014695, COSV58682746, COSV58721651; ClinVar: likely pathogenic; called by pindel, varscan2
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 228/443 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CNTN2 | c.2962G>A p.G988R | Missense Mutation (SNP) | VAF 399/601 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV59352729; called by muse, mutect2, varscan2
- COL25A1 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 153/334 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV101211490, COSV67649583; called by muse, mutect2, varscan2
- COL6A1 | c.623C>A p.T208K | Missense Mutation (SNP) | VAF 252/594 reads (42%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.928); catalogued as rs372199631; called by muse, mutect2, varscan2
- CREB3 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 145/305 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as CM1212878; called by muse, mutect2, varscan2
- DIAPH2 | c.1127A>T p.Q376L | Missense Mutation (SNP) | VAF 146/147 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61292226; called by muse, mutect2, varscan2
- DNAH7 | c.5029G>A p.A1677T | Missense Mutation (SNP) | VAF 143/337 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs551190156; called by muse, mutect2, varscan2
- ELFN1 | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 343/705 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs756943282; called by muse, mutect2, varscan2
- GPC1 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 380/800 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs765822451; called by muse, mutect2, varscan2
- INAVA | c.1090C>T p.L364F | Missense Mutation (SNP) | VAF 503/840 reads (60%) | SIFT tolerated (0.7); PolyPhen benign (0.3); catalogued as COSV100950163; called by muse, mutect2, varscan2
- MUC16 | c.38701G>A p.G12901S | Missense Mutation (SNP) | VAF 99/199 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.745); catalogued as rs528735934, COSV67456842; called by muse, mutect2, varscan2
- OR52K2 | c.542G>A p.C181Y | Missense Mutation (SNP) | VAF 250/477 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs747040626; called by muse, mutect2, varscan2
- PDS5A | c.1267G>C p.A423P | Missense Mutation (SNP) | VAF 179/562 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100337572; called by muse, mutect2, varscan2
- TGFBR2 | c.1483del p.R495Efs*23 | Frame Shift Del (DEL) | VAF 154/216 reads (71%) | catalogued as CM064334, COSV55443391, COSV55447248; called by pindel, varscan2
- ZNF225 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 210/419 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV53470998; called by muse, mutect2, varscan2
- ZNF648 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 171/874 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.2); catalogued as COSV60570087, COSV60570322; called by muse, mutect2, varscan2
- ADGRA1 | c.1355C>A p.P452H | Missense Mutation (SNP) | VAF 266/542 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- CDC42BPA | c.2650T>A p.S884T | Missense Mutation (SNP) | VAF 229/731 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- CLSTN2 | c.692T>C p.I231T | Missense Mutation (SNP) | VAF 41/394 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- CNTN5 | c.278A>C p.E93A | Missense Mutation (SNP) | VAF 139/268 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DUS3L | c.116A>T p.E39V | Missense Mutation (SNP) | VAF 392/392 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, varscan2
- FAM186A | c.6925T>C p.S2309P | Missense Mutation (SNP) | VAF 275/527 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HOXC10 | c.410G>A p.C137Y | Missense Mutation (SNP) | VAF 354/772 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, varscan2
- KLHL2 | c.678G>A p.W226* | Nonsense Mutation (SNP) | VAF 131/314 reads (42%) | called by muse, mutect2, varscan2
- MBTD1 | c.571G>C p.V191L | Missense Mutation (SNP) | VAF 158/350 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, varscan2
- MEGF8 | c.3802C>G p.L1268V (on ENST00000251268 / NM_001271938.2; = p.L1201V on NM_001410.3) | Missense Mutation (SNP) | VAF 314/668 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, varscan2
- MSLN | c.1856C>T p.T619I (on ENST00000382862 / NM_013404.4; = p.T611I on NM_005823.6) | Missense Mutation (SNP) | VAF 330/720 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.015); called by muse, varscan2
- PCDHGB5 | c.813G>T p.E271D | Missense Mutation (SNP) | VAF 211/426 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- PLCG2 | c.3699_3704del p.K1233_F1235delinsN | In Frame Del (DEL) | VAF 88/232 reads (38%) | called by pindel, varscan2
- PREX2 | c.3512C>A p.S1171* | Nonsense Mutation (SNP) | VAF 154/366 reads (42%) | called by muse, mutect2, varscan2
- SCN2A | c.2945T>C p.L982P | Missense Mutation (SNP) | VAF 183/360 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFP62 | c.192C>G p.D64E (on ENST00000502412 / NM_001377944.1; = p.D31E on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 257/594 reads (43%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZMYM1 | c.2740G>A p.D914N | Missense Mutation (SNP) | VAF 99/225 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CTNNA2 | c.457C>T p.L153= | Silent (SNP) | VAF 140/312 reads (45%) | called by muse, varscan2
- DCC | c.3594G>T p.L1198= | Silent (SNP) | VAF 174/395 reads (44%) | called by muse, varscan2
- GTF2A2 | c.210T>C p.N70= | Silent (SNP) | VAF 155/309 reads (50%) | catalogued as rs1308280404; called by muse, mutect2, varscan2
- GYG1 | c.1032A>G p.K344= | Silent (SNP) | VAF 188/413 reads (46%) | called by muse, varscan2
- HCAR3 | c.627C>T p.A209= | Silent (SNP) | VAF 268/530 reads (51%) | called by muse, varscan2
- MALRD1 | c.2964C>T p.L988= | Silent (SNP) | VAF 130/320 reads (41%) | called by muse, varscan2
- PDXK | c.936G>T p.L312= | Silent (SNP) | VAF 105/215 reads (49%) | called by muse, mutect2, varscan2
- PDZRN3 | c.1137C>T p.P379= | Silent (SNP) | VAF 114/258 reads (44%) | catalogued as rs749686351, COSV55215704; called by muse, mutect2, varscan2
- PLEKHB2 | c.99C>T p.I33= | Silent (SNP) | VAF 139/432 reads (32%) | catalogued as COSV99301802; called by muse, mutect2, varscan2
- ADGRE2 | c.2463+1347T>C | Intron (SNP) | VAF 195/425 reads (46%) | called by muse, mutect2, varscan2
- RASGRF2 | c.1390+387A>C | Intron (SNP) | VAF 246/516 reads (48%) | called by muse, varscan2
